Somatic mutation profile of tumor specimen TCGA-3H-AB3U-01A (aliquot TCGA-3H-AB3U-01A-21D-A39R-32) from TCGA case TCGA-3H-AB3U, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 71.8 years (26,220 days).
Specimen TCGA-3H-AB3U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2054d74-4b70-4914-b791-68dca77c289d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3H-AB3U-10A (Blood Derived Normal), aliquot TCGA-3H-AB3U-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50e97c20-f0af-43ec-8592-648d15f36d18

The open-access MAF lists 23 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 15, Frame Shift Del 3, Silent 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.6722C>T p.P2241L | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1399244128; called by muse, mutect2, varscan2
- CNOT3 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55368245; called by muse, mutect2, varscan2
- MACROD2 | c.1334C>T p.A445V (on ENST00000642719; = p.A417V on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs529893943; called by muse, mutect2, varscan2
- RXFP2 | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs201347289; called by muse, mutect2, varscan2
- TMEM94 | c.1953C>A p.N651K | Missense Mutation (SNP) | VAF 70/274 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs760821386; called by muse, mutect2, varscan2
- TULP1 | c.1132C>A p.R378S | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV57693435; called by muse, mutect2, varscan2
- UBE3D | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.929); catalogued as COSV52757177; called by muse, mutect2, varscan2
- ADAMTS4 | c.2013G>T p.K671N | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- BAP1 | c.1253_1262del p.Y418Wfs*9 | Frame Shift Del (DEL) | VAF 46/74 reads (62%) | called by mutect2, pindel, varscan2
- DTWD2 | c.319G>C p.V107L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.191); called by muse, mutect2
- GAA | c.635A>C p.E212A | Missense Mutation (SNP) | VAF 58/97 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HDAC1 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KRT34 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- LRRC7 | c.2570T>A p.V857D (on ENST00000651989 / NM_001370785.2; = p.V824D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- MMP2 | c.1381C>G p.L461V | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBEAL2 | c.2440C>T p.Q814* | Nonsense Mutation (SNP) | VAF 80/115 reads (70%) | called by muse, mutect2, varscan2
- OGDHL | c.2777T>C p.L926P | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RBL2 | c.1968_1972del p.G657Efs*11 | Frame Shift Del (DEL) | VAF 25/121 reads (21%) | called by mutect2, pindel, varscan2
- SETD2 | c.5993_5995delinsG p.Q1998Rfs*3 | Frame Shift Del (DEL) | VAF 37/50 reads (74%) | called by pindel, varscan2*
- TEDC2 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ASXL1 | c.4257G>A p.K1419= | Silent (SNP) | VAF 83/160 reads (52%) | called by muse, mutect2, varscan2
- GCN1 | c.741C>G p.A247= | Silent (SNP) | VAF 47/95 reads (49%) | called by muse, mutect2, varscan2
- XPO6 | c.526C>T p.L176= | Silent (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
